Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7197, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7197-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]		Case ID	OpenClinica Subject ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
[REDACTED]		[REDACTED]	[REDACTED]	Stomach segment with the plate-like tumor of 6 x 5.5 cm in size, with entire wall layers invasion. Greater and lesser curvature lymph nodes are hyperemic. Omentum is without changes.	Adenocarcinoma, with subserosa infiltration. Morphological features of the tumor structure may suggest its neuroendocrinal origin. Fifteen dissected lymph nodes demonstrate reactive changes. Omentum is without changes.		

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Pylorus
Tumor size: 5.5 x 0 x 6 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade:
Tumor extent: Subserosa
Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15)
Lymphatic invasion: Not specified
Venous invasion: Absent
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Lateralit
y

Date of
Procure
ment

NA

Source: NCI Genomic Data Commons file a3fdc63f-3454-43a2-b059-22900d86f6dc (TCGA-BR-7197.D8D0B7E5-98C6-404D-921E-F4AB8EBF7C28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).